Surgical pathology report (de-identified scan), TCGA case TCGA-ZC-AAAF, project TCGA-THYM (Thymoma), tissue source site  University of Mannheim, specimen TCGA-ZC-AAAF-01A (Primary Tumor).

Original report (translation):

Macroscopy:

Thanks for sending this mediastinal mass of a patient with myasthenia gravis.

Microscopy:

Histologically, a lobular constructed tumour that is predominantly lymphocyte-rich and only few sections with capsule-like border. The tumour shows only focally a biphasic structure consisting of spindle cells and a few accompanying lymphocytes. Medullary islands do not come to present. The tumour grows plump into the fat tissue before and at a location to the ink-marked surface. However, under the microscope there is in this area also no transection of the tumour visible (R0). Central extensive regressive changes, apparently as a result of tumour necrosis. The tumour is growing into the adventitia without penetrating into the lumen of the walled veins. In proximity to the tumour, normally developed thymus with preserved corticomedullary structure without prominent Hassallsche corpuscles and without thymitis. Furthermore, individual tiny mediastinal lymph nodes without significant follicular activation (rather regressive germinal centers).

Assessment:

This is an expanded type AB thymoma with expanded infiltration into the mediastinal fat (resection complete). There is a central regressive alteration. Stone-shaped cytological atypia in the lymphocyte-poor tumour sections. Thymic tissue concerning the age regular developed and without reference to a thymitis. Minimally activated, not enlarged and tumour free mediastinal lymph nodes.

Tumor stage : Masaoka II (marginal findings)

Resection : R0

Short report:

Date of tumour procurement:

Anatomic site:

Mediastinum

Final diagnosis:

Type AB thymoma

Discrepancy between histology on frozen section and paraffin section:

None

ICD-O 3
Thymoma, type AB, malignant 8552/3
Site ^{chf} Anterior mediastinum C38.1
^{path} Mediastinum NOS C38.3
W 3/12/14

Source: NCI Genomic Data Commons file b4f1880d-c38a-4be9-8114-bed66c2fcaf5 (TCGA-ZC-AAAF.7664B2FA-9917-4A65-90B1-A567B073E269.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).